Gene-level copy-number profile of tumor specimen TCGA-AG-3598-01A from TCGA case TCGA-AG-3598, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.3 years (25,324 days).
Specimen TCGA-AG-3598-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.5219e5a4-fe64-4030-8dce-a360ab6f08b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3598-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03d28749-3059-4e23-918f-6b8e4812491a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,757; copy number 2: 46,168; copy number 3: 6,866; copy number 4: 11; copy number 5: 14; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3598-01A-01D-0824-01): tumor purity 0.87, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:84,560,443–85,607,213, 11 genes, copy number 5–13: RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P, AL731532.2, GRID1-AS1.
- chr10:85,613,017–85,709,167, 4 genes, copy number 5: AC022028.3, AC022028.2, RN7SKP238, AC022028.1.

Autosomal genes at a single copy (total copy number 1): 4,377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
